Somatic mutation profile of tumor specimen TCGA-13-1477-01A (aliquot TCGA-13-1477-01A-01W-0545-08) from TCGA case TCGA-13-1477, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 49.6 years (18,111 days).
Specimen TCGA-13-1477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec8783bc-05d0-4334-b4b1-6f5e03e67c2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1477-10A (Blood Derived Normal), aliquot TCGA-13-1477-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018585e6-1e12-4bee-9292-a9c58f7cc47f

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAML1 | c.2680G>A p.V894I (on ENST00000321322; = p.V834I on NM_020693.4) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs768108077, COSV58381625; called by muse, mutect2, varscan2
- ENPP4 | c.791A>C p.D264A | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58089221; called by muse, mutect2, varscan2
- LAMA2 | c.5896G>T p.D1966Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV70344189, COSV70350934; called by muse, mutect2
- LIFR | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs773625392, COSV54692478; called by muse, mutect2, varscan2
- NTAN1 | c.890dup p.N297Kfs*2 | Frame Shift Ins (INS) | VAF 36/146 reads (25%) | catalogued as rs753931847; called by mutect2, varscan2
- STAG1 | c.3385A>T p.M1129L | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs759432131, COSV99365841; called by muse, mutect2, varscan2
- DIP2C | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYNE2 | c.941_949del p.Q314_L316del | In Frame Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- MAGEB1 | c.771C>T p.Y257= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs766373792, COSV66775251, COSV66775580; called by mutect2, varscan2
- RYR2 | c.201T>C p.F67= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV63692446; called by muse, mutect2, varscan2
